Surgical pathology report (de-identified scan), TCGA case TCGA-DV-5574, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-DV-5574-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS:

- 1. Kidney, right, "tumor #1" (excision): Renal cell carcinoma, clear cell type, Furhman nuclear grade II.
- 2. Kidney, right, "tumor #2" (excision): Renal cell carcinoma, clear cell type, Furhman nuclear grade II.
- 3. Soft tissue, "fat over right renal tumor" (excision): Fibroadipose tissue.

CLINICAL INFORMATION: Allocate Order to Protocol: [REDACTED] Brief Clinical History: VHL two large right renal masses Specimen Taken For Protocol: [REDACTED] - Yes

PROCEDURE: Pre-Operative Diagnosis: right renal masses Post-Operative Diagnosis: right renal masses Operative Findings: two large tumors one roughly 3 cm and one slightly smaller on the posterior side

SPECIMENS SUBMITTED: 1. TUMOR, Right renal # 1
2. TUMOR, Right renal # 2
3. FAT, Over right renal tumor

GROSS DESCRIPTION: Received are 3 formalin-filled containers labeled with the patient's name, medical record number, and further described as below:

- 1. "Right renal tumor #1" consists of a soft tissue fragment, 2.5 x 2 x 2 cm. The specimen is sectioned to reveal a tan cut surface. About 60% is procured for [REDACTED] and the rest preserved for Surgical Pathology. The procurement

Patient Identification

[page 2 of 2]
[REDACTED]

is performed by Dr. [REDACTED] In Surgical Pathology the specimen is received and matches the description above. The specimen is serially sectioned and put in white cassettes

2. "Right renal tumor" is a tan/brown fragment, 3.5 x 2.6 x 2.1 cm. One aspect appears to have capsule and possibly adjacent fat. The specimen is inked in black and bisected to reveal a golden-yellow nodular cut surface. Approximately 50% of the tumor is scooped out and without compromising margins and procured for [REDACTED] the remainder for Surgical Pathology. The procurement is performed by [REDACTED]. In Surgical Pathology, the specimen received matches the description above. The specimen is serially sliced and entirely submitted in white cassettes

3. "Fat over right renal tumor". The specimen consists of a tan soft tissue mass measuring 3.0 x 2.0 x 0.8 cm. The specimen is entirely submitted in a white cassette labeled [REDACTED] for permanent processing.

[REDACTED]

No consultants

[REDACTED]

Patient Identification

Source: NCI Genomic Data Commons file b7cfa23b-12e5-4e9b-9b3a-38d344c39ba0 (TCGA-DV-5574.6A820E34-7A1E-435E-91E5-6B19CFB68ABA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).